Surgical pathology report (de-identified scan), TCGA case TCGA-A2-A4RW, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Walter Reed, specimen TCGA-A2-A4RW-01A (Primary Tumor).

[page 1 of 3]
Name: [REDACTED] Age/Sex: [REDACTED] /F Location: [REDACTED]
Acct#: [REDACTED] Unit#: [REDACTED] Status: [REDACTED] Room/Bed: [REDACTED]

Specimen: [REDACTED] Received: [REDACTED]
Spec Type: SURGICAL P

Status: [REDACTED]
Subm Dr: [REDACTED]

PREOPERATIVE DIAGNOSIS

RIGHT BREAST CANCER INVASIVE

OPERATION PERFORMED

DATE:

DOCTOR:

PROCEDURE: MASTECTOMY MODIFIED RADICAL

ICD-0-3

carcinoma, infiltrating lobular, NOS 8520/3

Site: breast, NOS C50.9

lw
10/26/12

TISSUE REMOVED

- A. RT BREAST MASTECTOMY
- B. RT AXILLARY NODE DISSECTION

GROSS DESCRIPTION

RECEIVED IN 2 PARTS.

A RECEIVED LABELED [REDACTED] RIGHT BREAST STITCH 12 O'CLOCK IS A 650 GRAM SIMPLE MASTECTOMY SPECIMEN MEASURING 23.5 X 21.5 X 3.7 CM. THE NIPPLE IS UNREMARKABLE WITHIN A SKIN ELLIPSE MEASURING 23.5 X 12.5 CM. A SUTURE DENOTES 12 O'CLOCK. THE SUPERFICIAL ASPECT IS MARKED WITH BLUE INK, THE DEEP WITH BLACK. SECTIONING REVEALS A CENTRAL PORTION OF THE BREAST TO BE A MIXTURE OF TAN FIBROUS TISSUE AND YELLOW FAT. THE PERIMETER CONSISTS OF BLAND YELLOW FATTY TISSUE. IN THE 10 O'CLOCK AREA OF THE BREAST IS A FIRM MASS MEASURING 4 CM FROM MEDIAL TO LATERAL BY 3.5 CM FROM SUPERIOR TO INFERIOR AND 2.1 CM FROM ANTERIOR TO POSTERIOR. THERE IS A SMALL RIM OF FATTY TISSUE DEEP TO THE LESION. GROSSLY THERE IS AT LEAST 0.5 CM OF TISSUE. THIS DOES NOT INVOLVE THE SKIN GROSSLY. SECTIONS ARE SUBMITTED AS FOLLOWS: A1--NIPPLE, A2 AND 3--LESION IN DEEP MARGIN, A4--FAR LATERAL ASPECT OF LESION WITH SKIN, A5--GROSS MEDIAL ASPECT OF LESION 4 CM FROM A4, AND A10 IS THE TISSUE SUPERFICIAL TO A8 SUPERFICIAL TO DEEP MEASUREMENT. SECTIONS OF THE LESION ARE ALSO SUBMITTED PER PROTOCOL. A BOWTIE-SHAPED CLIP IS IDENTIFIED WITHIN THE LESION, A11--TUMOR, A12--UPPER INNER QUADRANT, A13--UPPER OUTER QUADRANT LATERAL TO LESION, A14--LOWER OUTER QUADRANT, A15--LOWER INNER QUADRANT.

4 x 3.5 x 2.1 cm

B RECEIVED LABELED [REDACTED] RIGHT AXILLARY NODE DISSECTION ARE 2 IRREGULAR PORTIONS OF YELLOW-RED FATTY TISSUE TOGETHER MEASURING 9 X 7 X 2.5 CM. THIS TISSUE IS EXAMINED FOR LYMPH NODES. THE LARGEST NODE WHICH IS 2.5 CM IN DIAMETER DEMONSTRATES A ROD-SHAPED METAL CLIP. IT HAS ILL-DEFINED BORDERS. ONE-HALF IS SUBMITTED IN B1. THE REMAINDER IS

[page 2 of 3]
Patient: [REDACTED]

(Continued)

Specimen: [REDACTED]

Received: [REDACTED]

Status: [REDACTED]

iq#: [REDACTED]

Spec Type: [REDACTED]

Subm Dr: [REDACTED]

GROSS DESCRIPTION

(Continued)

TAKEN PER PROTOCOL. ADDITIONAL NODES ARE ALSO IDENTIFIED AND SUBMITTED AS FOLLOWS. THERE IS A 2ND 2.5 CM LYMPH NODE WHICH IS GROSSLY UNREMARKABLE. ONE-HALF IS SUBMITTED AS B2. THE REMAINDER IS TAKEN PER PROTOCOL. A 1.7 CM LYMPH NODE IS BISECTED, ONE-HALF SUBMITTED IN B3, THE REMAINDER SUBMITTED PER PROTOCOL. ADDITIONAL NODES ARE THEN SUBMITTED AS FOLLOWS: B4--2 NODES EACH BISECTED, B5--3 NODES EACH BISECTED, B6--3 NODES EACH BISECTED, B7--1 NODE TOTAL, B8--5 NODES, B9--4 NODES, B10--4 NODES.

FORMALIN FIXATION TIME IS 6 HOURS AND 10 MINUTES.

PATH PROCEDURES

PROCEDURES:

88309, A BLK/15, B BLK/10

FINAL DIAGNOSIS

PART A RIGHT BREAST, SIMPLE MASTECTOMY:

1. INTRALOBULAR AND INFILTRATING LOBULAR CARCINOMA OF THE PLEOMORPHIC TYPE. THE INVASIVE COMPONENT SHOWS NUCLEAR GRADE 2/3, LOW MITOTIC INDEX AND TUBULE FORMATION 3 FOR A TOTAL NOTTINGHAM SCORE OF 6. LCIS WITH RARE FOCI OF LUMINAL NECROSIS COMPRISES APPROXIMATELY 30% OF THE TUMOR.
2. THE TUMOR HAS A MAXIMUM GROSS DIMENSION OF 4 CM ALTHOUGH RARE IN SITU AND INVASIVE FOCI ARE IDENTIFIED IN A RANDOM SECTION FROM THE LOWER OUTER QUADRANT.
3. INVASIVE TUMOR IS FOCALLY IDENTIFIED 4 MM FROM THE NEAREST INKED SUPERFICIAL MARGIN (A2) AND 4 MM FROM THE SKIN SURFACE (A4).
4. THE BIOPSY SITE [REDACTED] AND A BOWTIE-SHAPED CLIP ARE IDENTIFIED.
5. ALTHOUGH LYMPHOVASCULAR INVASION IS NOT IDENTIFIED, PERINEURAL INVASION IS PRESENT.

ILC 3/2/1
plus 4cm
30% LCIS
nec
-LVI

⊖ marg

PART B RIGHT AXILLA, LYMPH NODE DISSECTION: METASTATIC BREAST CARCINOMA IS IDENTIFIED IN ALL OF THE 27 LYMPH NODES EXAMINED. FOCAL EXTRANODAL EXTENSION INTO THE PERINODAL FAT IS PRESENT. A BIOPSY SITE INCLUDING A

27/27 LN
ENX

[page 3 of 3]
Patient: [REDACTED]		(Continued)	
Specimen:	Received:	Status:	Req#: [REDACTED]
	Spec Type: [REDACTED]	Subm Dr:	1, D.O.
FINAL DIAGNOSIS (Continued)			
ROD-SHAPED METAL CLIP IS ALSO PRESENT.			
Signed _____ Electronically signed by: _____, M.D.			

1. Discrepancy		
2. Discrepancy		
3. Discrepancy		
4. Discrepancy		
5. Discrepancy		
6. Discrepancy		
7. Discrepancy		
8. Discrepancy		
9. Discrepancy		
10. Discrepancy		
11. Discrepancy		
12. Discrepancy		
13. Discrepancy		
14. Discrepancy		
15. Discrepancy		
16. Discrepancy		
17. Discrepancy		
18. Discrepancy		
19. Discrepancy		
20. Discrepancy		
21. Discrepancy		
22. Discrepancy		
23. Discrepancy		
24. Discrepancy		
25. Discrepancy		
26. Discrepancy		
27. Discrepancy		
28. Discrepancy		
29. Discrepancy		
30. Discrepancy		
31. Discrepancy		
32. Discrepancy		
33. Discrepancy		
34. Discrepancy		
35. Discrepancy		
36. Discrepancy		
37. Discrepancy		
38. Discrepancy		
39. Discrepancy		
40. Discrepancy		
41. Discrepancy		
42. Discrepancy		
43. Discrepancy		
44. Discrepancy		
45. Discrepancy		
46. Discrepancy		
47. Discrepancy		
48. Discrepancy		
49. Discrepancy		
50. Discrepancy		
51. Discrepancy		
52. Discrepancy		
53. Discrepancy		
54. Discrepancy		
55. Discrepancy		
56. Discrepancy		
57. Discrepancy		
58. Discrepancy		
59. Discrepancy		
60. Discrepancy		
61. Discrepancy		
62. Discrepancy		
63. Discrepancy		
64. Discrepancy		
65. Discrepancy		
66. Discrepancy		
67. Discrepancy		
68. Discrepancy		
69. Discrepancy		
70. Discrepancy		
71. Discrepancy		
72. Discrepancy		
73. Discrepancy		
74. Discrepancy		
75. Discrepancy		
76. Discrepancy		
77. Discrepancy		
78. Discrepancy		
79. Discrepancy		
80. Discrepancy		
81. Discrepancy		
82. Discrepancy		
83. Discrepancy		
84. Discrepancy		
85. Discrepancy		
86. Discrepancy		
87. Discrepancy		
88. Discrepancy		
89. Discrepancy		
90. Discrepancy		
91. Discrepancy		
92. Discrepancy		
93. Discrepancy		
94. Discrepancy		
95. Discrepancy		
96. Discrepancy		
97. Discrepancy		
98. Discrepancy		
99. Discrepancy		
100. Discrepancy		

Source: NCI Genomic Data Commons file 320ab005-cbee-40ba-aa74-ba98c1d8328e (TCGA-A2-A4RW.C1D4D6BB-AF86-4208-A729-C61365941217.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).